Somatic mutation profile of tumor specimen TCGA-CN-4736-01A (aliquot TCGA-CN-4736-01A-01D-1434-08) from TCGA case TCGA-CN-4736, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; Tumor grade: G2; Age at diagnosis: 70.3 years (25,683 days).
Specimen TCGA-CN-4736-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dab84dbb-f1e9-4814-b8ed-c13c14dd4df7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-4736-10A (Blood Derived Normal), aliquot TCGA-CN-4736-10A-01D-1434-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/67614baf-7df1-4108-b69f-4f024497aaed

The open-access MAF lists 87 somatic variants for this specimen: 72 protein-altering or splice-affecting, 14 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 14, Nonsense Mutation 4, Frame Shift Del 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.358G>T p.E120* | Nonsense Mutation (SNP) | VAF 23/57 reads (40%) | hotspot (GDC flag); catalogued as CD972119, COSV58683444, COSV58717600; called by muse, mutect2, varscan2
- TP53 | c.578A>C p.H193P | Missense Mutation (SNP) | VAF 9/62 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs786201838, CM083194, CM951225, COSV52662414, COSV52663304, COSV52681707; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 18/84 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.1414G>A p.A472T | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs546681307, COSV51079230; called by muse, mutect2, varscan2
- ADIPOR2 | c.640C>T p.L214F | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.13); catalogued as COSV100840049; called by muse, mutect2, varscan2
- ARFGEF1 | c.2987G>A p.R996K | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99141325; called by muse, mutect2, varscan2
- ARMCX2 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 9/75 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV100168066; called by muse, mutect2, varscan2
- ASB2 | c.835G>A p.G279S | Missense Mutation (SNP) | VAF 20/102 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.703); catalogued as COSV100279243; called by muse, mutect2, varscan2
- ATP11C | c.1913A>T p.D638V | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV100557568; called by muse, mutect2, varscan2
- CACNA1G | c.6005A>T p.D2002V | Missense Mutation (SNP) | VAF 5/83 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV100661339; called by muse, mutect2
- CDH10 | c.862A>T p.I288F | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV100050437; called by muse, mutect2, varscan2
- CEP95 | c.2302G>T p.V768L | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.018); catalogued as COSV101616298; called by muse, mutect2, varscan2
- CHST9 | c.1188G>C p.K396N | Missense Mutation (SNP) | VAF 51/227 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52453189; called by muse, mutect2, varscan2
- CPLX4 | c.458C>T p.A153V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.98); catalogued as rs752019452, COSV55313481; called by muse, mutect2, varscan2
- CRACR2A | c.422A>T p.Y141F | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.664); catalogued as COSV99364708; called by muse, mutect2, varscan2
- CREBBP | c.3067G>A p.E1023K | Missense Mutation (SNP) | VAF 23/159 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV99062778, COSV99268953; called by muse, mutect2, varscan2
- CRYBG3 | c.8861A>G p.N2954S | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV99476684; called by muse, mutect2, varscan2
- DHODH | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.031); catalogued as rs771849639, COSV99536785; called by muse, mutect2, varscan2
- DNAH5 | c.7853A>T p.N2618I | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99446165; called by muse, mutect2, varscan2
- DPP6 | c.2114G>A p.R705H (on ENST00000377770 / NM_001364500.2; = p.R643H on NM_001936.5) | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs550563959, COSV59595739; called by muse, mutect2, varscan2
- E2F8 | c.1175C>T p.T392I | Missense Mutation (SNP) | VAF 19/104 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV100001356; called by muse, mutect2, varscan2
- ELAVL4 | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs868813722, COSV100836607; called by muse, mutect2, varscan2
- EPHA10 | c.2780G>A p.R927H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as rs1047206217, COSV100361085; called by muse, mutect2, varscan2
- EPHA4 | c.167A>C p.E56A | Missense Mutation (SNP) | VAF 31/162 reads (19%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.783); catalogued as COSV99915871; called by muse, mutect2, varscan2
- FIGN | c.886C>T p.Q296* | Nonsense Mutation (SNP) | VAF 8/96 reads (8%) | catalogued as COSV100291742; called by muse, mutect2
- FSIP2 | c.16402A>G p.T5468A | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV58083457; called by muse, mutect2, varscan2
- GAB3 | c.1454G>T p.R485I | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV100850439, COSV65818965, COSV65819607; called by muse, mutect2, varscan2
- GLCCI1 | c.1097G>T p.C366F | Missense Mutation (SNP) | VAF 74/259 reads (29%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.997); catalogued as rs1237380449, COSV99780174; called by muse, mutect2, varscan2
- HMGN4 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as rs747070546, COSV101110233; called by muse, mutect2, varscan2
- HOOK1 | c.772C>T p.Q258* | Nonsense Mutation (SNP) | VAF 6/78 reads (8%) | catalogued as COSV100969005; called by muse, mutect2
- ICE1 | c.2147A>T p.N716I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV99664018; called by muse, mutect2, varscan2
- ITGA9 | c.2581C>T p.P861S | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.044); catalogued as COSV99291905; called by muse, mutect2, varscan2
- KCNH7 | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 11/158 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as COSV100037642, COSV59816324; called by muse, mutect2
- KIAA1210 | c.3910C>A p.P1304T | Missense Mutation (SNP) | VAF 49/313 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV101273961, COSV68179998; called by muse, mutect2, varscan2
- LCP1 | c.881A>G p.K294R | Missense Mutation (SNP) | VAF 59/168 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.969); catalogued as COSV100549750; called by muse, mutect2, varscan2
- LONRF1 | c.1332A>T p.R444S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0.006); catalogued as COSV101238183; called by muse, mutect2, varscan2
- MACF1 | c.18101C>T p.P6034L (on ENST00000372915; = p.P4079L on NM_012090.5) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | catalogued as rs1230482374, COSV57129935; called by muse, mutect2, varscan2
- MAMLD1 | c.1394G>T p.S465I | Missense Mutation (SNP) | VAF 18/208 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99475624; called by muse, mutect2
- MLLT10 | c.935G>C p.G312A | Missense Mutation (SNP) | VAF 6/53 reads (11%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV100307584; called by muse, mutect2, varscan2
- MON2 | c.3533C>A p.P1178H | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.848); catalogued as COSV99741887; called by muse, mutect2, varscan2
- MUC16 | c.31025C>T p.S10342F | Missense Mutation (SNP) | VAF 23/79 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.918); catalogued as COSV101197897, COSV101198633; called by muse, mutect2, varscan2
- MYO16 | c.3532G>A p.V1178M | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.38); catalogued as COSV100696162; called by muse, mutect2, varscan2
- MYO18B | c.1836G>T p.Q612H | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV100122853; called by muse, mutect2
- NOTCH1 | c.1432T>A p.C478S | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99486066; called by muse, mutect2, varscan2
- NPC1L1 | c.3062A>G p.N1021S | Missense Mutation (SNP) | VAF 55/336 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); catalogued as COSV99203020; called by muse, mutect2, varscan2
- NRP2 | c.2218A>G p.S740G | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.061); catalogued as rs367890084; called by muse, mutect2, varscan2
- OR6K2 | c.424C>A p.Q142K | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.515); catalogued as COSV100656722; called by muse, mutect2, varscan2
- PDE6A | c.1765G>A p.A589T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as rs1463359682, COSV99677942; called by muse, mutect2, varscan2
- PDLIM7 | c.1172-1G>T p.X391_splice | Splice Site (SNP) | VAF 8/86 reads (9%) | catalogued as COSV100730153, COSV63082172; called by muse, mutect2
- PES1 | c.1135G>A p.D379N | Missense Mutation (SNP) | VAF 35/189 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58829353; called by muse, mutect2, varscan2
- PSIP1 | c.1550G>C p.R517T | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV101055453; called by muse, mutect2, varscan2
- PTPRN | c.1940G>A p.G647D | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.835); catalogued as COSV99833778; called by muse, mutect2
- RIMS2 | c.4027C>T p.R1343W | Missense Mutation (SNP) | VAF 23/135 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs754798117, COSV51650723; called by muse, mutect2, varscan2
- SCN10A | c.1685C>A p.S562Y | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.341); catalogued as COSV101479274, COSV71860455; called by muse, mutect2, varscan2
- SCN9A | c.5598G>T p.R1866S (on ENST00000303354; = p.R1855S on NM_002977.3) | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV100311784; called by muse, mutect2
- SLC5A11 | c.1717G>A p.A573T | Missense Mutation (SNP) | VAF 26/166 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs770129447, COSV100762700; called by muse, mutect2, varscan2
- SLC7A14 | c.1483C>A p.L495I | Missense Mutation (SNP) | VAF 40/326 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.836); catalogued as COSV99200392; called by muse, mutect2, varscan2
- SNTG2 | c.1021T>G p.W341G | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV100421711; called by muse, mutect2, varscan2
- SOX13 | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99689875; called by muse, mutect2, varscan2
- SPPL2C | c.1096C>T p.R366C | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.067); catalogued as rs369336082, COSV61291941; called by muse, mutect2, varscan2
- TERT | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.348); catalogued as COSV99717023; called by muse, mutect2
- TFPT | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV57837545; called by muse, mutect2, varscan2
- TRANK1 | c.1900C>T p.Q634* | Nonsense Mutation (SNP) | VAF 24/135 reads (18%) | catalogued as COSV100081896; called by muse, mutect2, varscan2
- TSPAN8 | c.301G>T p.A101S | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); catalogued as rs140330026, COSV99922470; called by muse, mutect2, varscan2
- TTN | c.70291G>C p.V23431L (on ENST00000591111; = p.V16007L on NM_003319.4) | Missense Mutation (SNP) | VAF 37/195 reads (19%) | PolyPhen benign (0.001); catalogued as COSV100599064; called by muse, mutect2, varscan2
- WFDC1 | c.97A>T p.N33Y | Missense Mutation (SNP) | VAF 27/160 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as COSV99550667; called by muse, mutect2, varscan2
- WNK1 | c.2132C>T p.S711L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV100266524; called by muse, varscan2
- XPNPEP2 | c.1502G>A p.R501Q | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.501); catalogued as rs763557610, COSV64369852; called by mutect2, varscan2
- ZNF770 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100695849; called by muse, mutect2, varscan2
- MOG | c.55C>A p.L19I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2
- TCHH | c.4198_4210del p.R1400Afs*20 | Frame Shift Del (DEL) | VAF 16/115 reads (14%) | called by mutect2, pindel, varscan2
- ZNF658 | c.1975G>A p.E659K | Missense Mutation (SNP) | VAF 73/362 reads (20%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CYP4F11 | c.414G>T p.L138= | Silent (SNP) | VAF 24/147 reads (16%) | catalogued as COSV99930680; called by muse, mutect2, varscan2
- CYP51A1 | c.486G>A p.K162= | Silent (SNP) | VAF 4/63 reads (6%) | catalogued as COSV99133665; called by muse, mutect2
- DLGAP1 | c.51C>T p.D17= | Silent (SNP) | VAF 17/52 reads (33%) | catalogued as COSV100228544; called by muse, mutect2, varscan2
- FAT2 | c.4527G>A p.V1509= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as COSV99941962; called by muse, mutect2, varscan2
- GSAP | c.1320G>T p.A440= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV99990020; called by muse, varscan2
- IL9R | c.12C>A p.G4= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV99729402; called by muse, mutect2, varscan2
- MMP16 | c.498A>T p.T166= | Silent (SNP) | VAF 10/93 reads (11%) | catalogued as COSV99686573; called by muse, mutect2, varscan2
- MYOCD | c.543C>T p.D181= | Silent (SNP) | VAF 31/187 reads (17%) | catalogued as rs368720240, COSV58497356; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR5M1 | c.900C>T p.A300= | Silent (SNP) | VAF 41/245 reads (17%) | catalogued as COSV101591538; called by muse, mutect2, varscan2
- PCDHA6 | c.963C>T p.D321= | Silent (SNP) | VAF 13/124 reads (10%) | catalogued as COSV100972156; called by muse, mutect2, varscan2
- SCP2D1 | c.381G>A p.K127= | Silent (SNP) | VAF 25/113 reads (22%) | catalogued as COSV99601924; called by muse, mutect2, varscan2
- TPTE2 | c.1353T>C p.G451= (on ENST00000400230 / NM_199254.2; = p.G374= on NM_130785.3) | Silent (SNP) | VAF 26/138 reads (19%) | catalogued as COSV99689846; called by muse, varscan2
- USF1 | c.339G>A p.E113= | Silent (SNP) | VAF 19/110 reads (17%) | catalogued as COSV99230844; called by muse, mutect2, varscan2
- ZC3HC1 | c.459G>A p.E153= | Silent (SNP) | VAF 5/80 reads (6%) | catalogued as COSV100315648; called by muse, mutect2
- OR52A4P | n.992G>T | RNA (SNP) | VAF 7/43 reads (16%) | called by mutect2, varscan2
